Gene-level copy-number profile of tumor specimen ALCH-AEJT-TTP1-A from ALCHEMIST case ALCH-AEJT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.1 years (24,146 days).
Specimen ALCH-AEJT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e623c4b7-753c-4bf5-a86a-4f5d61f70b5e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEJT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/62893d8d-18b2-449e-ae69-1507fe714673

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 2,147; copy number 2: 35,929; copy number 3: 18,107; copy number 4: 2,150; copy number 5: 53; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr6:73,322,837–73,364,171, 4 genes: SDCBP2P1, PAICSP3, DPPA5, KHDC3L.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 54 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:11,154,929–15,090,170, 53 genes, copy number 5: AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12, RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL109914.1, RNU6-793P, AL138720.1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 9 (within-gene range 2–9): GATD3A.

Autosomal genes at a single copy (total copy number 1): 2,122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
